Gene-level copy-number profile of specimen HCM-CSHL-0838-C18-85M from HCMI case HCM-CSHL-0838-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.6 years (21,407 days).
Specimen HCM-CSHL-0838-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56fff48f-7f0c-49bc-b743-11ca8bd8a8eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0838-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/35850e65-02e1-4a13-81c6-ed116465f0c3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 950; copy number 2: 19,717; copy number 3: 35,196; copy number 4: 2,472; copy number 5: 39; copy number 7: 8; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,085,628–144,373,659, 8 genes, copy number 7: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr8:64,091–167,043, 5 genes, copy number 8: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21.

Autosomal genes at a single copy (total copy number 1): 949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
